Somatic mutation profile of tumor specimen TCGA-DJ-A4UQ-01A (aliquot TCGA-DJ-A4UQ-01A-11D-A257-08) from TCGA case TCGA-DJ-A4UQ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nonencapsulated sclerosing carcinoma; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 60.5 years (22,097 days).
Specimen TCGA-DJ-A4UQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bbdb039-a1b3-4a3c-abd7-2938017f9e41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A4UQ-10A (Blood Derived Normal), aliquot TCGA-DJ-A4UQ-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e35e78b-5f76-4780-86d5-3ec9196c940b

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSDE1 | c.823C>T p.P275S (on ENST00000358528 / NM_001007553.3; = p.P244S on NM_007158.6) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1034873703, COSV99795079; called by muse, mutect2, varscan2
- DMTN | c.191A>T p.Y64F | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99741749, COSV99741808; called by muse, mutect2, varscan2
- DNAJC5G | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV99940554; called by muse, mutect2, varscan2
- FOXK2 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as rs770115350, COSV100082104; called by muse, mutect2, varscan2
- MFSD4A | c.962C>T p.T321M | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs750941919, COSV100901528; called by muse, mutect2, varscan2
- MTF2 | c.523T>G p.L175V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV100940126; called by muse, mutect2, varscan2
- NSD1 | c.7252C>T p.L2418F | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV100729195; called by muse, mutect2, varscan2
- PADI1 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs755235669, COSV100969126; called by muse, mutect2, varscan2
- PTPRZ1 | c.2453C>A p.P818H | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1349892260, COSV101100164, COSV66446495; called by muse, mutect2, varscan2
- REST | c.2737A>G p.I913V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100471023; called by muse, mutect2, varscan2
- SLC39A2 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100068592; called by muse, mutect2, varscan2
- STEAP3 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as COSV100713332; called by muse, mutect2, varscan2
- TBCEL | c.97C>A p.H33N | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.091); catalogued as COSV99412196; called by muse, mutect2, varscan2
- CPD | c.783G>T p.V261= | Silent (SNP) | VAF 43/203 reads (21%) | catalogued as COSV99852914; called by muse, mutect2, varscan2
- CSDE1 | c.822A>T p.V274= (on ENST00000358528 / NM_001007553.3; = p.V243= on NM_007158.6) | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV99795081; called by muse, mutect2, varscan2
- GIMAP5 | c.474C>T p.G158= | Silent (SNP) | VAF 50/135 reads (37%) | catalogued as COSV100500251; called by muse, mutect2, varscan2
